HCMI case HCM-EXPT-1215-C15 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/c9bb8d6f-cd84-4b15-9fa3-a3257726a338

Demographics
Sex at birth: male; Days to birth: -24,654 days (67.5 years before the index date).

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C15.9; Tissue or organ of origin: Esophagus, NOS; Site of resection or biopsy: Esophagus, NOS; Classification of tumor: primary; Tumor grade: G3; Esophageal columnar metaplasia present: No; Gastric esophageal junction involvement: Yes; Uicc clinical stage: Stage IIIB; Uicc pathologic m: M0; Uicc pathologic n: N0; Uicc pathologic stage: Stage IIA; Uicc pathologic t: T3; Uicc staging system edition: 7th.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel + Fluorouracil + Leucovorin + Oxaliplatin; Treatment intent type: Neoadjuvant; Days to treatment start: 114 days.

Biospecimens (1 sample)
- Sample HCM-EXPT-1215-C15-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
